Somatic mutation profile of tumor specimen 0D9AKM from CCDI case PBBHYH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,326 days).
Specimen 0D9AKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 144524bc-b9a2-4eb1-b902-fd00b0f6d65e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9AKN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84759a4a-99b2-41dc-b34e-e846a5e63d9d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 320/403 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SERPINB3 | c.181del p.Q61Kfs*29 | Frame Shift Del (DEL) | VAF 254/482 reads (53%) | catalogued as COSV52191721; called by mutect2, varscan2
- SSH3 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 61/770 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs201531520, COSV100354490; called by muse, mutect2
- E2F7 | c.2596C>T p.Q866* | Nonsense Mutation (SNP) | VAF 62/672 reads (9%) | called by muse, mutect2
- TAF2 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 24/634 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.042); called by muse, mutect2
- ZNF750 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 119/468 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DLD | c.337+45C>T | Intron (SNP) | VAF 224/297 reads (75%) | called by muse, mutect2
- GALNTL6 | c.138+41G>C | Intron (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- PDCD5 | c.-32G>C | 5'UTR (SNP) | VAF 40/64 reads (63%) | called by muse, mutect2
